Gene-level copy-number profile of tumor specimen TCGA-D5-6533-01A from TCGA case TCGA-D5-6533, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; Age at diagnosis: 68.4 years (24,971 days).
Specimen TCGA-D5-6533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9b5c794d-d1c4-4ca5-979d-1a4bde7b6868.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6533-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69c6ebfa-4a0a-43c5-a27b-4a0609308e48

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 25,872; copy number 2: 25,706; copy number 3: 6,587; copy number 4: 1,592; copy number 5: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6533-01A-11D-1717-01): tumor purity 0.69, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene: U3.
- chr12:29,500,840–29,784,759, 1 gene (within-gene range 0–1): TMTC1.
- chr12:29,658,376–30,695,869, 10 genes (within-gene range 0–1): RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8.
- chr18:4,430,945–4,459,458, 2 genes: AP005208.1, ELOCP27.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,806 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 3 (broad region; genes not listed).
- chr8:28,447,264–28,574,267, 4 genes, copy number 3 (within-gene range 1–3): AC025871.1, FZD3, MIR4288, RNA5SP259.
- chr8:29,333,064–31,546,735, 55 genes, copy number 3–5: DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1.
- chr9:18,858,906–37,047,237, 371 genes, copy number 3 (broad region; genes not listed).
- chr13:21,790,537–89,992,878, 922 genes, copy number 3–4 (broad region; genes not listed).
- chr13:94,574,054–114,337,626, 316 genes, copy number 3 (broad region; genes not listed).
- chr17:142,789–2,685,615, 104 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:18,289,343–18,359,300, 1 gene, copy number 4 (within-gene range 1–4): AL049646.1.
- chr20:18,313,765–19,056,796, 24 genes, copy number 4 (within-gene range 1–4): ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1.
- chr20:21,742,303–22,685,344, 13 genes, copy number 4 (within-gene range 1–4): SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747.
- chr20:23,362,182–25,452,628, 63 genes, copy number 4 (broad region; genes not listed).
- chr20:26,167,817–26,251,546, 1 gene, copy number 4 (within-gene range 1–4): MIR663AHG.
- chr20:28,563,850–64,313,132, 918 genes, copy number 4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
